Somatic mutation profile of tumor specimen 0DTYB7 from CCDI case PBCKKG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (5,980 days).
Specimen 0DTYB7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e69421e1-5e6c-445b-b5d7-eda9fde0cb11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYB0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/039b71da-25d8-42ce-861e-48fd607a9d0e

The open-access MAF lists 14 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 4, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 691/1584 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAM47A | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 416/959 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.653); catalogued as rs1362509719, COSV60493840; called by muse, mutect2, varscan2
- GLT8D2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 90/708 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs777460443, COSV62560950; called by muse, mutect2, varscan2
- TASP1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 459/1033 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs1042479531; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 35/1509 reads (2%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- FFAR2 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 19/607 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.282); called by muse, mutect2
- KALRN | c.3414C>T p.S1138= | Silent (SNP) | VAF 91/711 reads (13%) | catalogued as rs781542196, COSV53781262, COSV99567171; called by muse, mutect2, varscan2
- NONO | c.249C>T p.P83= | Silent (SNP) | VAF 211/1246 reads (17%) | catalogued as rs1036770687; called by muse, mutect2, varscan2
- PRSS2 | c.372C>T p.S124= | Silent (SNP) | VAF 92/1124 reads (8%) | called by muse, mutect2
- ADGRG2 | c.227-45T>A | Intron (SNP) | VAF 30/300 reads (10%) | called by muse, mutect2, varscan2
- FRMD8 | c.1-31C>T | Intron (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- PCID2 | c.37-96G>T | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as COSV55814251; called by muse, mutect2
- SIK3 | c.1788+50T>G | Intron (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- UBN1 | chr16:4847400 G>A | 5'Flank (SNP) | VAF 11/45 reads (24%) | catalogued as rs1256408986; called by muse, mutect2, varscan2
